Somatic mutation profile of tumor specimen TCGA-B0-5104-01A (aliquot TCGA-B0-5104-01A-01D-1421-08) from TCGA case TCGA-B0-5104, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-B0-5104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 744ad89b-d372-4e1d-8b25-bc9e472b9032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5104-11A (Solid Tissue Normal), aliquot TCGA-B0-5104-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/738e97ed-c5d4-4fdd-84d1-c96d020d765e

The open-access MAF lists 62 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 15, Nonsense Mutation 4, Frame Shift Del 4, Splice Site 3, In Frame Del 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM10 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as COSV53051057; called by muse, mutect2
- ALPP | c.1245C>A p.Y415* | Nonsense Mutation (SNP) | VAF 20/132 reads (15%) | catalogued as rs752955692, COSV67396201, COSV67396216; called by muse, mutect2, varscan2
- BMS1 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.136); catalogued as rs1485096253, COSV65733602; called by muse, mutect2, varscan2
- CCNB2 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55595301; called by muse, mutect2, varscan2
- CGNL1 | c.2886G>T p.E962D | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV55566527; called by muse, mutect2, varscan2
- CSGALNACT1 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 36/103 reads (35%) | catalogued as COSV59976557; called by muse, mutect2, varscan2
- CUBN | c.9418G>C p.A3140P | Missense Mutation (SNP) | VAF 110/398 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); catalogued as COSV100913065, COSV64713937; called by muse, varscan2
- DARS1 | c.812-2A>G p.X271_splice | Splice Site (SNP) | VAF 24/96 reads (25%) | catalogued as COSV51537716; called by muse, mutect2, varscan2
- EIF2AK1 | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV52238510; called by muse, mutect2, varscan2
- EMSY | c.3382C>G p.L1128V | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV58259525; called by muse, mutect2, varscan2
- EXOSC9 | c.635del p.R212Qfs*5 | Frame Shift Del (DEL) | VAF 34/196 reads (17%) | catalogued as COSV54666218; called by mutect2, pindel*, varscan2
- FSIP2 | c.15965A>T p.E5322V | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV58083706; called by muse, mutect2, varscan2
- G6PC | c.67T>A p.Y23N | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53830729; called by muse, mutect2, varscan2
- GIPC3 | c.253A>T p.K85* | Nonsense Mutation (SNP) | VAF 24/91 reads (26%) | catalogued as COSV59258825; called by muse, mutect2, varscan2
- GRIA1 | c.1218C>A p.N406K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV53599201, COSV99035759; called by muse, mutect2, varscan2
- HDAC9 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV101286708, COSV67771657; called by muse, mutect2, varscan2
- HMCN1 | c.9173T>G p.I3058S | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54894250; called by muse, mutect2, varscan2
- IRS1 | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV59334826; called by muse, mutect2, varscan2
- KCNJ15 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV60810684; called by muse, mutect2, varscan2
- LCLAT1 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58372193; called by muse, mutect2, varscan2
- MYH13 | c.2950G>T p.E984* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV52825930, COSV52826733; called by muse, mutect2, varscan2
- NAV1 | c.4658G>A p.R1553H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55216704; called by muse, mutect2, varscan2
- NRAP | c.4360A>C p.I1454L (on ENST00000359988 / NM_001322945.2; = p.I1419L on NM_006175.4) | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63489835; called by muse, mutect2, varscan2
- PARP1 | c.2684T>C p.I895T | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64690095; called by muse, mutect2, varscan2
- PBRM1 | c.2622_2624del p.K874_I875delinsN | In Frame Del (DEL) | VAF 11/42 reads (26%) | catalogued as COSV56271939; called by mutect2, pindel, varscan2
- PDE12 | c.837del p.F279Lfs*11 | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | catalogued as COSV60818513; called by pindel, varscan2*
- PPM1E | c.1883C>T p.T628I | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV57573178; called by muse, mutect2, varscan2
- RAB37 | c.366G>T p.R122S (on ENST00000392613 / NM_001006638.3; = p.R115S on NM_175738.5) | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.562); catalogued as COSV61193990; called by muse, mutect2, varscan2
- RAPGEF2 | c.2438G>C p.G813A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52427071; called by muse, mutect2, varscan2
- RND1 | c.550T>A p.S184T | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV59045142; called by muse, mutect2, varscan2
- RTN4IP1 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as rs202157885; called by muse, mutect2
- SDHAF4 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV65085131; called by muse, mutect2, varscan2
- SH2B1 | c.1023G>T p.E341D | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.037); catalogued as COSV59460207, COSV59462299; called by muse, mutect2, varscan2
- SLC17A9 | c.773T>A p.L258H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64847127; called by muse, mutect2, varscan2
- SLC1A5 | c.566+2T>G p.X189_splice | Splice Site (SNP) | VAF 3/11 reads (27%) | catalogued as COSV101314757; called by muse, mutect2
- TGM5 | c.1954G>C p.D652H (on ENST00000220420 / NM_201631.4; = p.D570H on NM_004245.4) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV55009782; called by muse, mutect2, varscan2
- TSBP1 | c.379+1G>C p.X127_splice (on ENST00000617061; = p.X144_splice on NM_006781.5) | Splice Site (SNP) | VAF 11/61 reads (18%) | catalogued as rs775160108, COSV100898735, COSV66658137; called by muse, mutect2, varscan2
- VWF | c.4822A>G p.T1608A | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as CM163391, COSV54617674; called by muse, mutect2, varscan2
- WDR24 | c.392G>A p.R131H (on ENST00000248142; = p.R69H on NM_032259.4) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV50197153, COSV99555842; called by muse, mutect2
- XRN2 | c.2047G>C p.V683L | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs377309279, COSV65869252; called by muse, mutect2, varscan2
- ZC3H3 | c.1079A>C p.K360T | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV52789294; called by muse, mutect2, varscan2
- ZKSCAN1 | c.1454G>T p.G485V | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60873726; called by muse, mutect2, varscan2
- CIAPIN1 | c.471_472insTGTA p.Q158Cfs*11 | Frame Shift Ins (INS) | VAF 34/154 reads (22%) | called by mutect2, varscan2
- ERCC6 | c.1249del p.V417Cfs*23 | Frame Shift Del (DEL) | VAF 32/190 reads (17%) | called by pindel, varscan2
- RNASE11 | c.464del p.N155Ifs*23 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- YAP1 | c.286_288del p.F96del | In Frame Del (DEL) | VAF 6/53 reads (11%) | called by pindel, varscan2
- BIRC6 | c.4581C>A p.V1527= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as COSV70198323; called by muse, mutect2, varscan2
- CARD6 | c.1044G>A p.K348= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV54565736; called by muse, mutect2, varscan2
- CSMD3 | c.6363G>T p.V2121= (on ENST00000297405 / NM_001363185.1; = p.V2017= on NM_052900.3) | Silent (SNP) | VAF 25/146 reads (17%) | catalogued as COSV52158696, COSV52182456; called by muse, mutect2, varscan2
- DACT1 | c.1500C>T p.N500= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as COSV60020444, COSV60021385; called by muse, mutect2, varscan2
- DHRS4 | c.177G>T p.V59= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as COSV57480622; called by muse, mutect2, varscan2
- HSD17B11 | c.306C>T p.S102= | Silent (SNP) | VAF 105/378 reads (28%) | catalogued as COSV64154268; called by muse, mutect2, varscan2
- LBX2 | c.501G>A p.L167= (on ENST00000377566 / NM_001282430.2; = p.L163= on NM_001009812.2) | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV52034860; called by muse, mutect2, varscan2
- MMP28 | c.1449C>T p.D483= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- OPHN1 | c.2268G>A p.K756= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1215178038, COSV62781818; called by muse, mutect2, varscan2
- PSMC1 | c.378T>G p.S126= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV54320657; called by muse, mutect2, varscan2
- SCYL2 | c.504G>A p.L168= | Silent (SNP) | VAF 36/188 reads (19%) | catalogued as COSV62568495; called by muse, mutect2, varscan2
- SDSL | c.99T>A p.P33= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV61884548; called by muse, mutect2, varscan2
- SLC16A8 | c.1062C>T p.G354= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1022452009, COSV57635056; called by muse, mutect2, varscan2
- UBN1 | c.2454G>A p.T818= | Silent (SNP) | VAF 34/147 reads (23%) | catalogued as rs1458992854, COSV52167269; called by muse, mutect2, varscan2
- ZNF215 | c.1218C>A p.P406= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as COSV53492671; called by muse, mutect2, varscan2
- POLR3GL | c.*2G>A | 3'UTR (SNP) | VAF 85/356 reads (24%) | catalogued as COSV100996756; called by muse, mutect2, varscan2
